FM case AD2921 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Other and unspecified parts of biliary tract.
https://portal.gdc.cancer.gov/cases/d8a4dd90-8200-47d2-a507-704669b13879

Male, 75.7 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the biliary tract; metastasis biopsied or resected from the peritoneum. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Metastatic.
